Gene-level copy-number profile of tumor specimen ALCH-B2NF-TTP1-A from ALCHEMIST case ALCH-B2NF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.2 years (24,533 days).
Specimen ALCH-B2NF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f66c3832-ddfe-4851-abc8-b1e12ee9e3f2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2NF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/edd3b6c1-368f-4a0b-a536-b291aea1dc33

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15; copy number 2: 57,180; copy number 3: 651; copy number 4: 480; copy number 5: 78.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 78 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:23,529,504–27,710,803, 78 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
